Somatic mutation profile of tumor specimen MP2PRT-PARJVW-TMP1-A (aliquot MP2PRT-PARJVW-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARJVW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,159 days).
Specimen MP2PRT-PARJVW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d62041cf-9d58-4ac7-8d58-700a00b3b425.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARJVW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARJVW-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df2938f7-7df4-42cf-a591-d15e995944ea

The open-access MAF lists 78 somatic variants for this specimen: 57 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 20, Nonsense Mutation 5, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 138/388 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ADGRV1 | c.4789G>C p.E1597Q | Missense Mutation (SNP) | VAF 129/415 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV67996486; called by muse, mutect2, varscan2
- AMER2 | c.1180C>G p.P394A | Missense Mutation (SNP) | VAF 185/480 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100766267; called by muse, mutect2, varscan2
- CD8A | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 213/636 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.12); catalogued as COSV99374665; called by muse, mutect2, varscan2
- CDH12 | c.1714G>C p.E572Q | Missense Mutation (SNP) | VAF 168/505 reads (33%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.784); catalogued as COSV101201876; called by muse, mutect2, varscan2
- DNAH2 | c.6316C>T p.R2106C | Missense Mutation (SNP) | VAF 170/389 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs200178920; called by muse, mutect2, varscan2
- DOK2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 309/766 reads (40%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs539220753, COSV52390033; called by muse, mutect2
- FMR1NB | c.627G>C p.W209C | Missense Mutation (SNP) | VAF 130/189 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV63272768; called by muse, mutect2, varscan2
- GALNT13 | c.1140C>G p.F380L | Missense Mutation (SNP) | VAF 91/247 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.388); catalogued as COSV67216729; called by muse, mutect2, varscan2
- GPRC6A | c.749C>G p.S250* | Nonsense Mutation (SNP) | VAF 20/430 reads (5%) | catalogued as COSV59954233; called by muse, mutect2
- L3MBTL2 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 32/512 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs1464006642; called by muse, mutect2
- LOXL4 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 187/555 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.071); catalogued as COSV99583724; called by muse, mutect2, varscan2
- LUZP2 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 83/257 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.096); catalogued as COSV61215296; called by muse, mutect2, varscan2
- MED12 | c.3330C>G p.F1110L | Missense Mutation (SNP) | VAF 127/198 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100375834; called by muse, varscan2
- MUC5B | c.11312C>G p.S3771C | Missense Mutation (SNP) | VAF 176/828 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as rs755993768; called by muse, mutect2
- NALCN | c.4949G>C p.R1650P | Missense Mutation (SNP) | VAF 139/465 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.176); catalogued as rs970102740; called by muse, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 100/361 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PARP4 | c.4927G>A p.E1643K | Missense Mutation (SNP) | VAF 161/431 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101131372; called by muse, mutect2
- PLXNA4 | c.5532C>G p.F1844L | Missense Mutation (SNP) | VAF 192/505 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV58148773; called by muse, mutect2, varscan2
- RETREG1 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs995763555; called by muse, mutect2, varscan2
- SLC24A5 | c.1017C>G p.F339L | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV51047749; called by muse, mutect2, varscan2
- TBC1D4 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 321/927 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as COSV100884604; called by muse, mutect2, varscan2
- TET2 | c.2109G>C p.L703F | Missense Mutation (SNP) | VAF 138/377 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); catalogued as rs781224980; called by muse, mutect2, varscan2
- TLCD3B | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 201/473 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs140155911; called by muse, varscan2
- VANGL1 | c.182C>G p.S61C | Missense Mutation (SNP) | VAF 25/502 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV59619274; called by muse, mutect2
- AASDH | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 137/352 reads (39%) | called by muse, varscan2
- AC090517.4 | c.1953G>C p.M651I | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AKAP10 | c.1847C>G p.S616* | Nonsense Mutation (SNP) | VAF 71/251 reads (28%) | called by muse, mutect2, varscan2
- ANGPTL4 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 25/622 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.13); called by muse, mutect2
- ANKRD17 | c.1600C>G p.Q534E | Missense Mutation (SNP) | VAF 110/333 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ARHGEF16 | c.1027T>C p.F343L | Missense Mutation (SNP) | VAF 116/370 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CERT1 | c.2159C>T p.S720L (on ENST00000405807 / NM_001130105.1; = p.S592L on NM_005713.3) | Missense Mutation (SNP) | VAF 113/373 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- DNAH9 | c.4393G>A p.D1465N | Missense Mutation (SNP) | VAF 52/511 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.097); called by muse, mutect2
- FAM171B | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FREM2 | c.7862C>T p.S2621F | Missense Mutation (SNP) | VAF 20/672 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- FSIP2 | c.14996C>T p.S4999L | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- HFE | c.1004C>G p.S335* | Nonsense Mutation (SNP) | VAF 61/230 reads (27%) | called by muse, mutect2, varscan2
- HSPA4L | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 92/285 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL17RC | c.1843G>A p.V615M (on ENST00000295981 / NM_153461.4; = p.V529M on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 241/710 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRX2 | c.116C>G p.S39W | Missense Mutation (SNP) | VAF 205/595 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KCNV1 | c.942G>C p.L314F | Missense Mutation (SNP) | VAF 59/535 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- LRRCC1 | c.1966G>C p.D656H | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- LRRN3 | c.189C>G p.F63L | Missense Mutation (SNP) | VAF 107/304 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NFATC3 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 79/270 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- NPAP1 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 144/411 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PLCE1 | c.2846C>G p.P949R | Missense Mutation (SNP) | VAF 13/435 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2
- PRSS53 | c.1473C>G p.F491L | Missense Mutation (SNP) | VAF 135/632 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SETX | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 15/413 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SHCBP1 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SHPK | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 136/403 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- SOGA3 | c.1010C>A p.P337H | Missense Mutation (SNP) | VAF 254/762 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SRRM2 | c.513C>T p.Y171= | Splice Region (SNP) | VAF 113/275 reads (41%) | called by muse, mutect2, varscan2
- TJP1 | c.4976C>A p.P1659H | Missense Mutation (SNP) | VAF 247/581 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- TRPS1 | c.121C>T p.Q41* (on ENST00000220888 / NM_001330599.2; = p.Q54* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 173/458 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.33151G>A p.E11051K (on ENST00000591111; = p.E10124K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/647 reads (3%) | PolyPhen benign (0.006); called by muse, mutect2
- UBA2 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UGT3A2 | c.580C>G p.H194D | Missense Mutation (SNP) | VAF 99/366 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- ADRA1A | c.180C>T p.V60= | Silent (SNP) | VAF 136/464 reads (29%) | called by muse, mutect2, varscan2
- BBX | c.9C>T p.G3= | Silent (SNP) | VAF 80/222 reads (36%) | called by muse, mutect2, varscan2
- CNTN5 | c.720G>A p.A240= | Silent (SNP) | VAF 98/278 reads (35%) | catalogued as rs749442209, COSV54288611, COSV99682538; called by muse, mutect2, varscan2
- DST | c.4368C>T p.I1456= (on ENST00000361203 / NM_001374722.1; = p.I1130= on NM_015548.5) | Silent (SNP) | VAF 86/275 reads (31%) | called by muse, mutect2, varscan2
- FAT3 | c.12246C>T p.F4082= | Silent (SNP) | VAF 127/314 reads (40%) | catalogued as rs751877950; called by muse, varscan2
- FSIP2 | c.14709C>T p.I4903= | Silent (SNP) | VAF 39/132 reads (30%) | called by muse, mutect2, varscan2
- IGLV4-60 | c.362A>T p.*121= | Silent (SNP) | VAF 64/97 reads (66%) | called by muse, mutect2, varscan2
- KIF2A | c.1464C>G p.L488= | Silent (SNP) | VAF 70/200 reads (35%) | catalogued as COSV66945365; called by muse, varscan2
- LRIT1 | c.480C>T p.L160= | Silent (SNP) | VAF 206/514 reads (40%) | called by muse, mutect2, varscan2
- LRP2 | c.660G>A p.P220= | Silent (SNP) | VAF 93/303 reads (31%) | catalogued as rs781149561, COSV55578018; called by muse, mutect2, varscan2
- MICAL2 | c.4074G>A p.V1358= | Silent (SNP) | VAF 191/533 reads (36%) | catalogued as rs899913549, COSV99811488; called by muse, mutect2, varscan2
- OGT | c.1461G>A p.K487= | Silent (SNP) | VAF 9/240 reads (4%) | called by muse, mutect2
- PPRC1 | c.3471G>A p.V1157= | Silent (SNP) | VAF 102/343 reads (30%) | called by muse, mutect2, varscan2
- RFXANK | c.708G>C p.R236= | Silent (SNP) | VAF 173/457 reads (38%) | called by muse, varscan2
- RNF223 | c.729C>T p.L243= | Silent (SNP) | VAF 110/308 reads (36%) | catalogued as rs775705819; called by muse, mutect2, varscan2
- SNTN | c.381C>G p.L127= | Silent (SNP) | VAF 146/405 reads (36%) | catalogued as COSV59539162; called by muse, mutect2, varscan2
- SPHK1 | c.303C>A p.I101= (on ENST00000392496 / NM_001355139.2; = p.I115= on NM_021972.4) | Silent (SNP) | VAF 163/449 reads (36%) | called by muse, mutect2, varscan2
- TFAP2D | c.441C>G p.L147= | Silent (SNP) | VAF 204/548 reads (37%) | called by muse, varscan2
- TP53RK | c.96C>T p.F32= | Silent (SNP) | VAF 271/859 reads (32%) | catalogued as rs1372069240; called by muse, mutect2, varscan2
- USP32 | c.651A>G p.L217= | Silent (SNP) | VAF 20/578 reads (3%) | called by muse, mutect2
- TGIF1 | c.-407C>T | 5'UTR (SNP) | VAF 29/791 reads (4%) | catalogued as rs1035633620; called by muse, mutect2
